Somatic mutation profile of tumor specimen TCGA-4Z-AA82-01A (aliquot TCGA-4Z-AA82-01A-11D-A391-08) from TCGA case TCGA-4Z-AA82, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.9 years (21,893 days).
Specimen TCGA-4Z-AA82-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c3f33fd-2cf2-44ed-b05f-40f36e122296.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA82-10A (Blood Derived Normal), aliquot TCGA-4Z-AA82-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10e820d6-5ae7-46a6-9372-37ed2e4a260e

The open-access MAF lists 112 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.2161C>A p.Q721K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV65901088; called by muse, mutect2, varscan2
- ADGRL3 | c.2625C>G p.I875M (on ENST00000506720 / NM_001322402.2; = p.I807M on NM_015236.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV72230668; called by muse, mutect2
- ADRA1A | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 98/145 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52375599; called by muse, mutect2, varscan2
- AGO2 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55053333; called by muse, mutect2, varscan2
- AKNAD1 | c.2125G>T p.V709F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV62204233; called by muse, mutect2, varscan2
- ARSA | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1430695346, COSV53351455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRNL1 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV61806718; called by muse, mutect2, varscan2
- AVL9 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as COSV59469817; called by muse, mutect2, varscan2
- BCLAF1 | c.1182T>G p.F394L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV62146322; called by muse, varscan2
- BEND3 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554231295, COSV64682447; called by muse, mutect2, varscan2
- BHMT | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as rs1045603041, COSV57155963; called by muse, mutect2, varscan2
- BRF1 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59272445; called by muse, mutect2
- CDHR5 | c.1702C>T p.P568S (on ENST00000358353 / NM_001171968.2; = p.P574S on NM_021924.5) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV57646389; called by muse, mutect2, varscan2
- COL11A1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771139447, COSV62178322; called by muse, mutect2, varscan2
- CRYBG3 | c.8848C>G p.H2950D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51716684; called by muse, mutect2, varscan2
- CTSV | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52345941; called by muse, mutect2
- CYP27A1 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51467954, COSV99298828; called by muse, mutect2
- CYTH4 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs373316484; called by muse, mutect2, varscan2
- DISC1 | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.382); catalogued as COSV54420192; called by muse, mutect2, varscan2
- DNAH11 | c.3381G>C p.W1127C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60961746, COSV60984991; called by muse, mutect2
- DNHD1 | c.11526G>C p.Q3842H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99600937; called by muse, mutect2
- EMC7 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs994825366, COSV99854975; called by muse, mutect2
- FAM102A | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV66195143; called by muse, mutect2
- FAM120B | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs146980569; called by muse, mutect2, varscan2
- FAM47A | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.715); catalogued as rs1330286658, COSV60500204; called by muse, mutect2, varscan2
- FMOD | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs752609674, COSV61610508; called by muse, mutect2, varscan2
- FRMPD2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs748676341, COSV59714786, COSV59719823; called by muse, mutect2, varscan2
- GRIN2D | c.1664C>A p.P555H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54382557; called by muse, mutect2, varscan2
- HDLBP | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60501590; called by muse, mutect2, varscan2
- HIP1 | c.2409G>C p.E803D | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV61191983; called by muse, mutect2, varscan2
- INSRR | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100948068; called by muse, mutect2
- ITGAL | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100776346; called by muse, mutect2, varscan2
- JAKMIP1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as rs1282195574, COSV51530755; called by muse, mutect2
- KCNK9 | c.422A>T p.K141M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV57289166; called by muse, mutect2, varscan2
- KDM6A | c.3981del p.A1328Lfs*28 | Frame Shift Del (DEL) | VAF 33/52 reads (63%) | catalogued as COSV65046938; called by mutect2, pindel, varscan2
- KRTAP4-4 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs767618099, COSV66811589; called by muse, mutect2, varscan2
- MACF1 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 33/167 reads (20%) | catalogued as rs778673967, COSV58364653; called by muse, mutect2, varscan2
- MAMLD1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV53381518; called by muse, mutect2, varscan2
- MLLT10 | c.2336C>T p.S779L (on ENST00000307729 / NM_001195626.3; = p.S795L on NM_004641.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1485908140, COSV56999119; called by muse, mutect2, varscan2
- MNDA | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100933438; called by muse, mutect2, varscan2
- MRPL28 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99170796; called by muse, mutect2, varscan2
- MUC17 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs1172657345, COSV59332641; called by muse, mutect2, varscan2
- NCAM1 | c.1237C>T p.Q413* (on ENST00000316851 / NM_181351.5; = p.Q403* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100378537; called by muse, mutect2, varscan2
- NCAPH | c.844A>T p.T282S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV53639365; called by muse, mutect2, varscan2
- NRAS | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101056121; called by muse, mutect2, varscan2
- PAM | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV57213011, COSV57214744; called by muse, mutect2, varscan2
- PCSK5 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV65092954; called by muse, mutect2, varscan2
- PDCD6 | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99373094; called by muse, mutect2, varscan2
- PDS5B | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59735380; called by muse, mutect2, varscan2
- PKD1L2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55172163; called by muse, mutect2, varscan2
- PLEKHA3 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1438931296, COSV52296889; called by muse, mutect2, varscan2
- PLXNB2 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs376982545; called by muse, mutect2, varscan2
- POGK | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV63312564; called by muse, mutect2
- PTPRD | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV61937662; called by muse, mutect2, varscan2
- RABL6 | c.282del p.K95Rfs*7 | Frame Shift Del (DEL) | VAF 82/229 reads (36%) | catalogued as COSV61041730; called by mutect2, pindel, varscan2
- RAP2C | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV61683797; called by muse, mutect2, varscan2
- REV3L | c.3500C>G p.T1167S | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV62624099; called by muse, mutect2, varscan2
- RO60 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66475173; called by muse, mutect2
- ROBO2 | c.3587C>A p.P1196H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV59931663; called by muse, mutect2, varscan2
- SERPINA12 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV57946534; called by muse, mutect2, varscan2
- SF1 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57117881; called by muse, mutect2, varscan2
- SIM1 | c.1563G>C p.R521S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53497393; called by muse, mutect2, varscan2
- SLIT3 | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1408386266, COSV60635282; called by muse, mutect2, varscan2
- SPINT2 | c.161G>C p.W54S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56649264; called by muse, mutect2, varscan2
- STX19 | c.678A>G p.I226M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57402296; called by muse, mutect2, varscan2
- SWI5 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60793305; called by muse, mutect2, varscan2
- TBX5 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.185); catalogued as COSV59866000; called by muse, mutect2, varscan2
- TIAM2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs768356762, COSV59705210; called by muse, mutect2, varscan2
- TMPRSS4 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1049950180, COSV71110665; called by muse, mutect2, varscan2
- TP53BP1 | c.2527C>G p.P843A | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV55510893; called by muse, mutect2, varscan2
- TRIM36 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV56693786; called by muse, mutect2, varscan2
- UBR2 | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV65752936; called by muse, mutect2, varscan2
- UGT2B15 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV100592451; called by muse, mutect2, varscan2
- WSCD1 | c.629G>C p.C210S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58498831; called by muse, mutect2, varscan2
- XPR1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV62560960; called by muse, mutect2, varscan2
- ZDHHC22 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60059199; called by muse, mutect2, varscan2
- ZEB1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV58056280; called by muse, mutect2
- ZNF343 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53855787; called by muse, mutect2, varscan2
- ZNF449 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV59348272; called by muse, mutect2, varscan2
- ASNS | c.1256del p.P419Hfs*3 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- ERICH6 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.106); called by muse, mutect2
- IGBP1P2 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 40/282 reads (14%) | called by muse, mutect2, varscan2
- RXRA | c.230dup p.M77Ifs*104 | Frame Shift Ins (INS) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- C1QTNF9B | c.387C>T p.D129= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs147006375; called by muse, mutect2, varscan2
- CADM2 | c.981C>T p.P327= (on ENST00000407528 / NM_001167674.2; = p.P329= on NM_153184.4) | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV67408263; called by muse, mutect2, varscan2
- CD163L1 | c.1440G>A p.G480= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1230422250, COSV100550631; called by muse, mutect2
- CLRN1 | c.225G>A p.G75= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV58997416; called by muse, mutect2, varscan2
- CREBBP | c.3396C>T p.P1132= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs749030378, COSV52122170; called by muse, mutect2
- DGKK | c.2151G>C p.L717= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101053207; called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- GP2 | c.1023G>C p.L341= (on ENST00000381362 / NM_001007240.3; = p.L338= on NM_001502.4) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV56897063; called by muse, mutect2, varscan2
- HPS4 | c.1056C>T p.L352= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV61106104; called by muse, mutect2, varscan2
- HPS4 | c.570C>T p.L190= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs201820144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.11505A>G p.S3835= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1389279179, COSV52695588; called by muse, mutect2, varscan2
- MRC1 | c.1959C>T p.S653= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- NOS1 | c.3732C>T p.N1244= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV57623086; called by muse, mutect2, varscan2
- PCDHA8 | c.1716C>A p.G572= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1554139660, COSV65333532; called by muse, mutect2, varscan2
- RAPGEF1 | c.1803C>A p.S601= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs758302661, COSV100940749, COSV64702586; called by muse, mutect2
- SEC24A | c.1167G>T p.T389= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV59750156; called by muse, mutect2, varscan2
- SGK2 | c.312G>A p.G104= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs943590059, COSV58312340; called by muse, mutect2, varscan2
- SLC15A1 | c.393G>C p.L131= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV64713085; called by muse, mutect2
- SLC4A5 | c.924C>T p.L308= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs766872138, COSV61033614; called by muse, mutect2, varscan2
- SLC5A12 | c.789C>T p.C263= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV54825411; called by muse, mutect2, varscan2
- SPTBN2 | c.2745C>A p.A915= | Silent (SNP) | VAF 52/97 reads (54%) | catalogued as COSV59462131; called by muse, mutect2, varscan2
- TBC1D4 | c.2178A>T p.P726= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV66492632; called by muse, mutect2, varscan2
- ULK1 | c.2574G>A p.L858= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs1467352275, COSV58860306; called by muse, mutect2, varscan2
- XYLT1 | c.900C>T p.F300= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54498031; called by muse, mutect2, varscan2
- ZNF567 | c.1476C>T p.L492= (on ENST00000536254 / NM_001322913.1; = p.L461= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV62446677; called by muse, mutect2, varscan2
- C16orf91 | c.*48C>G | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100113764, COSV59949560, COSV59949818; called by muse, mutect2
- CEP295 | chr11:93731547 G>C | 3'Flank (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- KCNK1 | c.356-16558G>A | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23968C>A | Intron (SNP) | VAF 20/143 reads (14%) | catalogued as COSV67441265, COSV67451095; called by muse, mutect2, varscan2
